Somatic mutation profile of tumor specimen TCGA-3A-A9IU-01A (aliquot TCGA-3A-A9IU-01A-11D-A397-08) from TCGA case TCGA-3A-A9IU, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.7 years (23,998 days).
Specimen TCGA-3A-A9IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01dd808a-4baa-4fa5-ae76-d8758767b3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IU-10A (Blood Derived Normal), aliquot TCGA-3A-A9IU-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec42e07d-d713-4a2b-b0a3-232f10a4b89f

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Nonsense Mutation 3, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 53/136 reads (39%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/327 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs770480372, COSV54053359; called by muse, mutect2, varscan2
- ABCA13 | c.10903G>A p.V3635I | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570952854, COSV101446729; called by muse, mutect2, varscan2
- ACOT12 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100297125; called by muse, mutect2, varscan2
- ADGRG4 | c.4010C>A p.T1337K | Missense Mutation (SNP) | VAF 125/235 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99796401; called by muse, mutect2, varscan2
- ARAP1 | c.2770G>A p.V924M (on ENST00000393609 / NM_001040118.2; = p.V679M on NM_015242.4) | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100501617; called by muse, mutect2, varscan2
- ATP10A | c.2418A>C p.E806D | Missense Mutation (SNP) | VAF 111/442 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100791462; called by muse, mutect2, varscan2
- C1orf43 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1241559197, COSV99672087; called by muse, mutect2, varscan2
- CELF4 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 50/146 reads (34%) | catalogued as COSV100611912; called by muse, mutect2, varscan2
- DSEL | c.1602G>T p.Q534H | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100025989; called by muse, mutect2, varscan2
- DSEL | c.1601A>T p.Q534L | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100025990; called by muse, mutect2, varscan2
- ELOVL2 | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100676021; called by muse, mutect2, varscan2
- FAM217B | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 62/234 reads (26%) | catalogued as rs760895424, COSV100674627; called by muse, mutect2, varscan2
- FOSL2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99268491; called by muse, mutect2, varscan2
- LMAN2L | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99383563; called by muse, mutect2, varscan2
- MEX3C | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs143556022; called by muse, mutect2, varscan2
- NMS | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.215); catalogued as rs201102943, COSV65259146; called by muse, mutect2, varscan2
- PKD1 | c.7189A>G p.S2397G | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV99238859; called by muse, mutect2
- RALYL | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as rs745691095, COSV72818739; called by muse, mutect2, varscan2
- RORB | c.1111G>A p.A371T (on ENST00000396204 / NM_001365023.1; = p.A360T on NM_006914.4) | Missense Mutation (SNP) | VAF 169/595 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163653001, COSV100974457; called by muse, mutect2, varscan2
- TNIK | c.3604G>A p.G1202S | Missense Mutation (SNP) | VAF 125/448 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99459101; called by muse, mutect2, varscan2
- TP53 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 259/600 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV53716244; called by muse, varscan2
- TYR | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 160/545 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.169); catalogued as rs148815276, COSV99074275; called by muse, mutect2, varscan2
- VPS33B | c.357+1G>A p.X119_splice | Splice Site (SNP) | VAF 119/481 reads (25%) | catalogued as COSV100325710; called by muse, mutect2, varscan2
- ZBED4 | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); catalogued as rs914269152, COSV99351574; called by muse, mutect2, varscan2
- FLVCR1 | c.1381_1384dup p.S462Yfs*7 | Frame Shift Ins (INS) | VAF 77/460 reads (17%) | called by mutect2, pindel, varscan2
- ABHD8 | c.1050C>T p.G350= | Silent (SNP) | VAF 125/301 reads (42%) | catalogued as rs536645024, COSV56044080; called by muse, mutect2, varscan2
- ILDR1 | c.390C>T p.L130= | Silent (SNP) | VAF 62/221 reads (28%) | catalogued as rs202089487, COSV99878818; called by muse, mutect2, varscan2
- KDM4C | c.2334C>T p.C778= | Silent (SNP) | VAF 88/229 reads (38%) | catalogued as rs773293209, COSV67190861; called by muse, mutect2, varscan2
- LNPEP | c.2007A>G p.Q669= | Silent (SNP) | VAF 107/405 reads (26%) | catalogued as rs541171362, COSV99183588; called by muse, mutect2, varscan2
- MEX3C | c.1125G>A p.G375= | Silent (SNP) | VAF 96/287 reads (33%) | catalogued as COSV101346323; called by muse, varscan2
- MICU1 | c.435G>A p.V145= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV100741889; called by muse, mutect2, varscan2
- MTCL1 | c.2151C>T p.H717= (on ENST00000306329 / NM_001378206.1; = p.H357= on NM_015210.4) | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as rs1446574202, COSV60407052; called by muse, mutect2, varscan2
- NELL2 | c.1158C>A p.T386= | Silent (SNP) | VAF 69/323 reads (21%) | catalogued as COSV100420466; called by muse, mutect2, varscan2
- SACS | c.*692G>A | 3'UTR (SNP) | VAF 30/110 reads (27%) | catalogued as rs759926296, COSV54568963; called by muse, varscan2
